Surgical pathology report (de-identified scan), TCGA case TCGA-HQ-A2OE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HQ-A2OE-01A (Primary Tumor).

hw 9/16/11

Sample Type Tumour Primary

Sample Preparation
Site of Primary (Event)
Site of Tissue
Year of Sample Collection
Age at Sample Collection (yrs)
Sample Comments
Days to Procedure Date
Days to Diagnosis
Type of Procedure
Site of Primary (Histology)
Bilateral Disease
Tumour Size (cm)
Histology
Grade/Differentiation
Pathological T
Pathological N
Number of Nodes Sampled
Number of Nodes Positive
Clinical M
Histology Comments

Fresh Frozen
Bladder

0
15
Surgical resection
urinary bladder

3
papillary urothelial carcinoma
Grade X (Unknown)
T2a
N2

MX

1CD-0-3
carcinoma, urothelial, NOS 8/20/3
Site: bladder, NOS C67.9
hw 9/16/11

Source: NCI Genomic Data Commons file 74d30c4f-ae57-44af-aeac-63ab97e91259 (TCGA-HQ-A2OE.FFCA27E4-3A1F-4626-AB67-2DE62CAD713F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).